Surgical pathology report (de-identified scan), TCGA case TCGA-DQ-7588, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Of Michigan, specimen TCGA-DQ-7588-01A (Primary Tumor).

[page 1 of 3]
HISTORY:

with biopsy confirmed squamous cell carcinoma in the left retromolar trigone. Operative Procedure: Left resection left retromolar trigone.

GROSS:

1. "Posterior lateral tongue." Received fresh for frozen section analysis is a 1.2 cm fragment of mucosa. All tissues frozen.
- 1A. Frozen section control.
2. "Anterior lateral tongue." Received fresh for frozen section analysis are three tissue fragments, largest 1.3 cm. All tissues submitted for frozen section.
- 2A. Frozen section control.
3. "Mucosa adjacent to first molar." Received fresh for frozen section analysis are two 0.3 cm mucosal fragments. All tissues submitted for frozen section.
- 3A. Frozen section control.
4. "Anterior floor of mouth." Received fresh for frozen section analysis are two 0.6 cm mucosal fragments. All tissues submitted for frozen section.
- 4A. Frozen section control.
5. "Tongue base." Received fresh for frozen section analysis is a 1 cm fragment of mucosa. All tissues submitted for frozen section.
- 5A. Frozen section control.
6. "Retromolar trigone." Received fresh for frozen section analysis is a 0.3 cm fragment of mucosa. All tissues submitted for frozen section analysis.
- 6A. Frozen section control.
7. "Buccal mucosa." Received fresh for frozen section analysis is a 1.5 cm fragment of mucosa. All tissues submitted for frozen section.
- 7A. Frozen section control.
8. "Deep margin." Received fresh for frozen section analysis are two 0.2 cm tissue fragments. All tissues submitted for frozen section.
- 8A. Frozen section control.
9. "Soft palate." Received fresh for frozen section analysis are 2 fragments measuring 1.2 and 0.7 cm. All tissues submitted for frozen section.
- 9A. Frozen section control.
10. "Left retromolar trigone with tonsil." Received unoriented in a small container of formalin are two portions of tissue. The larger measures 3.3 x 3 x 1.7 cm. The smaller measures 1.4 x 0.5 x 0.4 cm. The larger portion consists of soft tissue including mucosa and tonsillar tissue. Within the tissue is an ulcerated lesion measuring 2.2 x 1.5 x 1 cm. The lesion reaches the anterior soft tissue and mucosal edge and focally reaches the superior mucosal soft tissue edge. The lesion is within 2 mm of the inferior soft tissue edge and posterior soft tissue edge. Lesion is also within 2 mm of the deep (lateral) soft tissue edge. The tumor is semi firm and white and well-demarcated. The soft tissue edges are inked green. Representative sections are submitted. Photographs are taken.
- 10A. Sample of superior edge.
- 10B-C. Sample of tumor showing anterior deep and posterior edges. (1ss each)
- 10D. Sample of inferior edge.
11. "Left neck section Level I." Received in formalin in a small container is a 7.2 x 5.6 x 2.8 cm portion of yellow fibroadipose tissue. A 4.2 x 2.2 cm submandibular gland is identified. Multiple polyps and lymph nodes are identified, ranging up to 1.5 cm.
- 11A. Submandibular gland.

[page 2 of 3]
11B. Multiple possible lymph nodes. [REDACTED]
11C-F. One bisected lymph node each. [REDACTED]
12. "Left neck section Level II." Received in formalin in a small container is a 9.2 x 5.3 x 3.2 cm irregular portion of pink-yellow fibroadipose tissue. Multiple possible lymph nodes are identified ranging up to 2.2 cm in greatest dimension. Cut surface of the largest lymph node is gray-white, and granular.
12A. Multiple possible lymph nodes. [REDACTED]
12B. One bisected lymph node. [REDACTED]
12C. One trisected lymph node [REDACTED]
12D. One bisected lymph node. [REDACTED]
12E. Largest lymph node. [REDACTED]
13. "Left neck dissection Level III." Received in formalin in a small container is a 4.5 x 3.6 x 1.8 cm irregular portion of pink-yellow fibroadipose tissue. Multiple possible lymph nodes are identified ranging up to 1.1 cm.
13A. Multiple possible lymph nodes. [REDACTED]
14. "Left neck dissection Level IV." Received in formalin in a small container is a 4.2 x 2.8 x 1.3 cm aggregate of yellow fibroadipose tissue. Multiple possible lymph nodes are identified, ranging up to 0.6 cm.
14A. Multiple possible lymph nodes. [REDACTED] Fat retained.

FROZEN SECTION REPORT

1-9) Negative for neoplasm [REDACTED]

I, [REDACTED], have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section report.

MICROSCOPIC DIAGNOSIS:

1-9. Intraoperative margins, please see above for sites, excision: Negative for carcinoma.

10. Left retromolar trigone and tonsil, resection: Invasive moderately differentiated squamous cell carcinoma (2.2 cm). Please see template.

11. Lymph nodes, left neck level I, dissection: Seven lymph nodes negative for malignancy. Unremarkable salivary gland.

12. Lymph nodes, left neck level II, dissection: Metastatic squamous cell carcinoma involving one of seven lymph nodes (1/7). No extranodal extension.

13. Lymph nodes, left neck level III, dissection: Seven lymph nodes negative for malignancy.

14. Lymph nodes, left neck level IV, dissection: Nine lymph nodes negative for malignancy.

I, [REDACTED] the signing staff pathologist, have personally examined and interpreted the slides from this case.

[page 3 of 3]
Close

Source: NCI Genomic Data Commons file 722b330f-dc37-4ff8-9de8-b549805e6c6b (TCGA-DQ-7588.3ADD1FAD-B2E3-4D4C-BC0D-E41E5EB51CC7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).